Somatic mutation profile of tumor specimen TCGA-CC-A9FW-01A (aliquot TCGA-CC-A9FW-01A-11D-A36X-10) from TCGA case TCGA-CC-A9FW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.1 years (24,891 days).
Specimen TCGA-CC-A9FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dd9c524-1fa9-4d0c-80ea-ce42eb405030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A9FW-10A (Blood Derived Normal), aliquot TCGA-CC-A9FW-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f3aeb00-6af2-42e6-a638-326013ca5125

The open-access MAF lists 156 somatic variants for this specimen: 125 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 29, Nonsense Mutation 11, Splice Site 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 42/116 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100856989; called by muse, mutect2, varscan2
- ADAD2 | c.925C>T p.P309S (on ENST00000315906 / NM_001145400.2; = p.P391S on NM_139174.4) | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV99235687; called by muse, mutect2, varscan2
- ADAMTS3 | c.1478G>C p.C493S | Missense Mutation (SNP) | VAF 101/144 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99711992; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2546T>A p.L849Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV99721097; called by muse, mutect2, varscan2
- ADNP | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs372148600, COSV100823852; called by muse, mutect2, varscan2
- ANKRD12 | c.4921G>T p.V1641F | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs779879268, COSV100042057, COSV50820609; called by muse, mutect2, varscan2
- APC | c.4619A>G p.E1540G | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99970135; called by muse, mutect2, varscan2
- ARL13B | c.961A>T p.K321* (on ENST00000394222 / NM_001174150.2; = p.K214* on NM_144996.4) | Nonsense Mutation (SNP) | VAF 135/423 reads (32%) | catalogued as COSV100115840; called by muse, mutect2, varscan2
- ARMC6 | c.784G>A p.A262T (on ENST00000392336; = p.A237T on NM_033415.4) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99523171; called by muse, mutect2, varscan2
- ASAP2 | c.2591G>C p.S864T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV99856410, COSV99856762; called by muse, mutect2, varscan2
- ASXL1 | c.471G>A p.Q157= | Splice Region (SNP) | VAF 13/161 reads (8%) | catalogued as COSV100039299, COSV100041028; called by muse, mutect2
- B4GALT5 | c.1022A>T p.Y341F | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1381169339, COSV100866923; called by muse, mutect2, varscan2
- BDH1 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100827243; called by muse, mutect2, varscan2
- C1orf53 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.23); catalogued as rs779133381, COSV100956494; called by muse, mutect2, varscan2
- CAST | c.1730G>A p.S577N (on ENST00000341926; = p.S660N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701278; called by muse, mutect2, varscan2
- CC2D1A | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.922); catalogued as COSV100528688; called by muse, mutect2, varscan2
- CDH13 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99230721; called by muse, mutect2, varscan2
- CDH8 | c.1724C>A p.P575Q | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100184049; called by muse, mutect2, varscan2
- CELF4 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 119/145 reads (82%) | SIFT tolerated (0.98); PolyPhen benign (0.06); catalogued as COSV100611984; called by muse, mutect2, varscan2
- CHEK1 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99629896; called by muse, mutect2, varscan2
- CHPF | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs775762046, COSV99705297; called by muse, mutect2, varscan2
- CLDN17 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433746016, COSV99729415; called by muse, mutect2, varscan2
- CNOT2 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs774964600, COSV99973092; called by muse, mutect2, varscan2
- COL11A2 | c.381G>C p.Q127H | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.048); catalogued as COSV59498412; called by muse, varscan2
- COL24A1 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 116/169 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748650963, COSV100992757; called by muse, mutect2, varscan2
- DACH2 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 123/145 reads (85%) | catalogued as COSV100913877; called by muse, mutect2, varscan2
- DNAH5 | c.4099A>T p.R1367W | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453975; called by muse, mutect2, varscan2
- DOCK4 | c.1625A>C p.Y542S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101447964; called by muse, mutect2, varscan2
- DPYSL3 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100575373; called by muse, mutect2, varscan2
- ELAC2 | c.1295A>T p.E432V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100568630; called by muse, mutect2, varscan2
- ERCC1 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV99185239; called by muse, mutect2, varscan2
- FANK1 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100904817; called by muse, mutect2, varscan2
- FCHSD1 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767554840, COSV99781519; called by muse, mutect2, varscan2
- FLNB | c.4690A>C p.K1564Q | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV99914748; called by muse, mutect2, varscan2
- FRMPD4 | c.3536A>G p.K1179R | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.355); catalogued as COSV101044027; called by muse, mutect2, varscan2
- GRIK3 | c.1555dup p.L519Pfs*72 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | catalogued as rs1226469622; called by mutect2, pindel, varscan2
- GRWD1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs140220072; called by muse, mutect2, varscan2
- H2AC15 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV100357114; called by muse, mutect2, varscan2
- H2BC4 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1373665078, COSV100020065, COSV58415545; called by muse, mutect2, varscan2
- IFRD2 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100269519, COSV100269811; called by muse, mutect2, varscan2
- IREB2 | c.66T>G p.H22Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99359732; called by muse, mutect2, varscan2
- KCNK3 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1244344621, COSV100257167; called by muse, mutect2, varscan2
- KDM5D | c.2913A>T p.E971D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV100522308; called by muse, mutect2, varscan2
- KNL1 | c.1920A>C p.E640D (on ENST00000346991 / NM_170589.5; = p.E614D on NM_144508.5) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV100706960; called by muse, mutect2, varscan2
- KTN1 | c.523+1G>A p.X175_splice | Splice Site (SNP) | VAF 94/168 reads (56%) | catalogued as COSV101255424; called by muse, mutect2, varscan2
- LAMB2 | c.3802G>T p.E1268* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100026480, COSV59733561; called by muse, mutect2, varscan2
- LMAN1L | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100547836; called by muse, mutect2, varscan2
- MCM3AP | c.4360A>T p.S1454C | Missense Mutation (SNP) | VAF 80/113 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99387487; called by muse, mutect2, varscan2
- MDFIC | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99995407; called by muse, mutect2, varscan2
- MEGF8 | c.7987C>G p.L2663V (on ENST00000251268 / NM_001271938.2; = p.L2596V on NM_001410.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99238930; called by muse, mutect2, varscan2
- MICU2 | c.664-2A>C p.X222_splice | Splice Site (SNP) | VAF 62/180 reads (34%) | catalogued as COSV101212490; called by muse, mutect2, varscan2
- MMP3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1487605173, COSV100243024; called by muse, mutect2, varscan2
- MROH2B | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV101270911; called by muse, mutect2, varscan2
- MYO1E | c.3032C>T p.T1011M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs546147455, COSV99896459; called by muse, mutect2, varscan2
- MYO5A | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62562917; called by muse, varscan2
- NAP1L3 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); catalogued as rs1274817954, COSV100220659; called by muse, mutect2, varscan2
- NHLRC3 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV101099036; called by muse, mutect2, varscan2
- NKAIN4 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941678; called by muse, mutect2, varscan2
- NUDCD1 | c.633A>C p.K211N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV99517682; called by muse, mutect2, varscan2
- OPALIN | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as rs770990264, COSV100959684, COSV100959688; called by muse, mutect2, varscan2
- OR4C11 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs113364923, COSV100155510, COSV56353443; called by muse, mutect2, varscan2
- OR5B17 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | catalogued as COSV100641958; called by muse, mutect2, varscan2
- OR5D14 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100162672, COSV59456041; called by muse, mutect2, varscan2
- OR5D14 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100162600; called by muse, mutect2, varscan2
- OR5W2 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100747747; called by muse, mutect2, varscan2
- OR8J3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV100041018, COSV56883000; called by muse, mutect2, varscan2
- PCDHGA9 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as COSV99546459; called by muse, mutect2, varscan2
- PDS5B | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 156/216 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as rs892869982, COSV100221499; called by muse, mutect2, varscan2
- PIKFYVE | c.2194A>G p.R732G | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100011412; called by muse, mutect2, varscan2
- PITHD1 | c.617A>T p.Q206L | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99862241; called by muse, mutect2, varscan2
- PKHD1 | c.2929A>G p.N977D | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); catalogued as rs749030797, COSV100584505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHB2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99301811; called by muse, mutect2, varscan2
- PMP22 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100397015; called by muse, mutect2, varscan2
- PTPRZ1 | c.4153G>T p.G1385C | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as rs1232485167, COSV101100805; called by muse, mutect2
- R3HDM1 | c.498-1G>A p.X166_splice | Splice Site (SNP) | VAF 26/103 reads (25%) | catalogued as COSV99926759; called by muse, mutect2, varscan2
- RAB43 | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV100167649, COSV59348980; called by muse, mutect2, varscan2
- RBBP8NL | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs1486166637, COSV99436958; called by muse, mutect2, varscan2
- REV3L | c.6983T>A p.I2328N | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100725675; called by muse, mutect2, varscan2
- RGL2 | c.1506G>A p.Q502= | Splice Region (SNP) | VAF 42/75 reads (56%) | catalogued as COSV101004836; called by muse, mutect2, varscan2
- RLF | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101035682; called by muse, mutect2, varscan2
- RNPEP | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1052128019, COSV99821850; called by muse, mutect2, varscan2
- RPS6KA3 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 26/33 reads (79%) | catalogued as COSV101084657, COSV65387180; called by muse, mutect2, varscan2
- RYR3 | c.9124T>C p.Y3042H (on ENST00000389232; = p.Y3043H on NM_001036.6) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.362); catalogued as COSV101214428; called by muse, mutect2, varscan2
- SEPTIN3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs868245028, COSV52173285; called by muse, mutect2, varscan2
- SERPINC1 | c.1189T>G p.S397A | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as CM002222, COSV100875120; called by muse, mutect2, varscan2
- SETX | c.4297A>C p.T1433P | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99810872; called by muse, mutect2, varscan2
- SLC16A14 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1388118440, COSV99725874; called by muse, mutect2, varscan2
- SLC16A9 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332626064, COSV101264477; called by muse, mutect2, varscan2
- SLC22A25 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.123); catalogued as COSV100123959; called by muse, mutect2, varscan2
- SLC35B4 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV65985528; called by muse, mutect2, varscan2
- SLC4A3 | c.2655C>A p.S885R | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99813201; called by muse, mutect2, varscan2
- SLC5A12 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | catalogued as rs865879642, COSV54823651; called by muse, mutect2
- SLC9A3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1183347565, COSV99376624; called by muse, mutect2, varscan2
- SP1 | c.2027A>T p.H676L (on ENST00000327443 / NM_138473.3; = p.H669L on NM_003109.1) | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100540852; called by muse, mutect2, varscan2
- SPATA1 | c.1300T>A p.Y434N | Missense Mutation (SNP) | VAF 171/265 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV99759946; called by muse, mutect2, varscan2
- SPRR2G | c.64A>T p.K22* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100907398; called by muse, mutect2, varscan2
- SRSF1 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.188); catalogued as COSV99365476; called by muse, mutect2, varscan2
- SUSD2 | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100844410; called by muse, mutect2, varscan2
- SUV39H2 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100543191; called by muse, mutect2, varscan2
- SZT2 | c.10282T>G p.W3428G (on ENST00000634258 / NM_001365999.1; = p.W3371G on NM_015284.4) | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs75906384, COSV100981341; called by muse, mutect2, varscan2
- TBC1D26 | c.75+2T>A p.X25_splice | Splice Site (SNP) | VAF 63/154 reads (41%) | catalogued as rs1228274937, COSV101343686; called by muse, mutect2, varscan2
- TBC1D31 | c.164A>C p.D55A | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99783209; called by muse, mutect2, varscan2
- TENM4 | c.7700G>A p.G2567D | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579061; called by muse, mutect2, varscan2
- TET1 | c.3755A>T p.E1252V | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV101018860; called by muse, mutect2, varscan2
- TG | c.8287T>A p.S2763T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.15); catalogued as COSV99603073; called by muse, mutect2, varscan2
- THBD | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 36/181 reads (20%) | catalogued as COSV101001920; called by muse, mutect2, varscan2
- TLL1 | c.2790A>T p.E930D | Missense Mutation (SNP) | VAF 123/187 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99289027; called by muse, mutect2, varscan2
- TMEM176B | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100423685; called by muse, mutect2, varscan2
- TMEM40 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV99277319; called by muse, mutect2, varscan2
- TMEM98 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs142287076; called by muse, mutect2, varscan2
- TRABD2A | c.844C>T p.P282S (on ENST00000409520 / NM_001277053.2; = p.P233S on NM_001080824.3) | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.257); catalogued as COSV100120275; called by muse, mutect2, varscan2
- TRAPPC10 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs759992126, COSV52377783; called by muse, mutect2, varscan2
- TSPAN9 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as COSV99170965; called by muse, mutect2, varscan2
- TTC21A | c.1320G>T p.M440I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100087653; called by muse, mutect2, varscan2
- UBAP2L | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99670562, COSV99672248; called by muse, mutect2, varscan2
- UCN | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 213/909 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as COSV99274552; called by muse, mutect2, varscan2
- WNK2 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370654793; called by muse, mutect2, varscan2
- BSN | c.10933del p.H3645Tfs*150 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- COL18A1 | c.19_28del p.G7Sfs*17 | Frame Shift Del (DEL) | VAF 34/49 reads (69%) | called by mutect2, pindel, varscan2
- COL18A1 | c.1777_1794del p.V593_F598del (on ENST00000359759 / NM_130444.3; = p.V358_F363del on NM_030582.4) | In Frame Del (DEL) | VAF 17/30 reads (57%) | called by mutect2, pindel, varscan2
- GGCX | c.1485_1500del p.F496Gfs*6 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PARP10 | c.1777+2_1777+18del p.X593_splice | Splice Site (DEL) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- RIBC2 | c.1101_1102insA p.Q368Tfs*11 | Frame Shift Ins (INS) | VAF 231/644 reads (36%) | called by mutect2, varscan2
- ABCA13 | c.11631C>T p.N3877= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as rs374031988; called by muse, mutect2, varscan2
- ACRBP | c.177C>T p.T59= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs752892968, COSV99976284; called by muse, mutect2, varscan2
- ADAM30 | c.2127G>T p.R709= | Silent (SNP) | VAF 59/91 reads (65%) | catalogued as COSV101023974; called by muse, mutect2, varscan2
- ALDH5A1 | c.162C>T p.L54= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs760612467, COSV100708921; called by muse, mutect2, varscan2
- APPL2 | c.903T>C p.Y301= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV51589795; called by muse, mutect2, varscan2
- CRELD2 | c.645C>T p.G215= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs777489583, COSV58208568; called by muse, mutect2, varscan2
- DENND1C | c.735C>T p.H245= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs746951264, COSV101200250; called by muse, mutect2, varscan2
- DIRAS2 | c.387C>T p.R129= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV101005899; called by muse, mutect2, varscan2
- ERBB4 | c.1641G>A p.E547= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV53554997; called by muse, mutect2, varscan2
- EZH2 | c.1134A>T p.T378= (on ENST00000460911 / NM_001203247.2; = p.T383= on NM_004456.5) | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV100236719; called by muse, mutect2, varscan2
- FGF8 | c.18C>T p.S6= | Silent (SNP) | VAF 40/195 reads (21%) | catalogued as COSV100199435; called by muse, mutect2, varscan2
- IGHV3-38 | c.192G>A p.L64= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs778816412; called by muse, mutect2, varscan2
- KIRREL3 | c.1776T>C p.G592= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV101375230; called by muse, mutect2, varscan2
- MN1 | c.615C>G p.G205= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100180124; called by muse, mutect2
- MON2 | c.3864A>G p.K1288= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV99743552; called by muse, mutect2, varscan2
- MTMR2 | c.324G>T p.T108= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as CD013478, COSV100656839, COSV60582201; called by muse, mutect2, varscan2
- MYO10 | c.2703G>A p.Q901= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99946236; called by muse, mutect2, varscan2
- NCOA6 | c.4440G>C p.V1480= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV100750334; called by muse, mutect2, varscan2
- NSFL1C | c.102G>A p.L34= | Silent (SNP) | VAF 68/142 reads (48%) | catalogued as COSV99401612; called by muse, mutect2, varscan2
- PCDH15 | c.1131C>T p.A377= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV100227305; called by muse, mutect2, varscan2
- POPDC2 | c.285G>A p.L95= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV99951154; called by muse, mutect2, varscan2
- RAB21 | c.228A>T p.A76= | Silent (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- SLFN11 | c.2250T>C p.S750= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV100391006; called by muse, mutect2, varscan2
- TMEM101 | c.639T>C p.P213= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs201655817, COSV99243966; called by muse, mutect2, varscan2
- TSLP | c.273G>T p.A91= | Silent (SNP) | VAF 114/271 reads (42%) | catalogued as COSV100789217; called by muse, mutect2, varscan2
- TUBA4A | c.1257C>T p.S419= | Silent (SNP) | VAF 93/177 reads (53%) | catalogued as rs199590938, COSV99850882; called by muse, mutect2, varscan2
- UBR4 | c.4695C>T p.S1565= | Silent (SNP) | VAF 133/197 reads (68%) | catalogued as COSV64382909; called by muse, mutect2, varscan2
- WNT3A | c.348C>A p.A116= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV99470147; called by muse, mutect2, varscan2
- ZNF831 | c.3501C>T p.P1167= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100926248; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6050615 C>A | 3'Flank (SNP) | VAF 59/85 reads (69%) | catalogued as COSV99290718; called by muse, mutect2, varscan2
- TIMM23 | chr10:45971967 del C | 5'Flank (DEL) | VAF 73/180 reads (41%) | called by mutect2, varscan2
